Surgical pathology report (de-identified scan), TCGA case TCGA-24-0968, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-0968-01A (Primary Tumor).

[page 1 of 5]
Patient Name:

DOB:

Accession:

Surgical Pathology Report

Final

SURGICAL PATHOLOGY REPORT FINAL

Patient Name: :

Address: :

Gender: F

DOB: :

Service:

Location:

MRN: :

Hospital #: :

Patient Type:

Accession #: :

Taken: :

Received:

Accessioned:

Reported:

Physician(s):

Other Related Clinical Data:

DIAGNOSIS:

SOFT TISSUE, OMENTUM, BIOPSY (INCLUDING FS1)

- METASTATIC POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA

SOFT TISSUE, "PELVIC MASS", EXCISION

- POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA

- OVARIAN TISSUE PRESENT

- FALLOPIAN TUBE WITH TUMOR INVOLVEMENT

- EXTENSIVE LYMPHOVASCULAR SPACE INVASION IDENTIFIED

SOFT TISSUE, MESENTERY, EXCISION

- METASTATIC POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA

SOFT TISSUE, "LARGE BOWEL LESION", EXCISION

- METASTATIC POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA

SOFT TISSUE, OMENTUM, EXCISION

- METASTATIC POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA

SOFT TISSUE, FALCIFORM LIGAMENT, EXCISION

- METASTATIC POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA

SOFT TISSUE, RIGHT HEMIDIAPHRAGM PERITONEUM, EXCISION

- METASTATIC POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA

LIVER, "LIVER NODULE," EXCISION

- METASTATIC POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA

UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY

- NO EVIDENCE OF MALIGNANCY

UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- INACTIVE ENDOMETRIUM

UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- ADENOMYOSIS

- LEIOMYOMATA (THE LARGEST MEASURING 3 CM)

UTERUS, SEROSA, TOTAL ABDOMINAL HYSTERECTOMY

- METASTATIC POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA

- SEROSAL ADHESIONS

OVARY, RIGHT, BILATERAL SALPINGO-OOPHORECTOMY

[page 2 of 5]
Patient Name:

DOB:

- MICROSCOPIC FOCUS OF SURFACE IMPLANT OF SEROUS ADENOCARCINOMA
FALLOPIAN TUBE, RIGHT, BILATERAL SALPINGO-OOPHORECTOMY
- METASTATIC POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA INVOLVING THE
SEROSA AND PARATUBAL SOFT TISSUE
OVARY, LEFT, BILATERAL SALPINGO-OOPHORECTOMY
- POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA
- EXTENSIVE LYMPHOVASCULAR INVASION IDENTIFIED
LARGE INTESTINE, RECTOSIGMOID, RESECTION
- METASTATIC POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA INVOLVING THE
SEROSA AND SUBSEROA
- TUMOR PRESENT AT RESECTION MARGIN
- METASTATIC POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA IN ONE PERICOLIC LYMPH
NODE (1/1)
- FOCAL ENDOMETRIOSIS AND ENDOSALPINGIOSIS
LARGE INTESTINE, ANASTOMOTIC DONUT, EXCISION
- NO EVIDENCE OF MALIGNANCY

By this signature, I attest that the above diagnosis is
based upon my personal
examination of the slides(and/or other material indicated in the
diagnosis).

***Report Electronically Reviewed and Signed Out By
Intraoperative Consultation:
FS1: Omentum, biopsy
- "adenocarcinoma, favor Mullerian origin," by

Microscopic Description and Comment:
Microscopic examination substantiates the above cited diagnosis..

History:

The patient is a year old woman with a history of ovarian cancer. Operative
procedure: Exploratory laparotomy, omentectomy, total abdominal hysterectomy.
Specimen(s) Received:
A: OMENTUM BIOPSY
B: PELVIC MASS
C: MESENTARY
D: LARGE BOWEL LESION
E: OMENTUM, ROUTINE
F: FALCIFORM LIGAMENT
G: PERITONEUM, RIGHT HEMI DIAPHRAGM
H: LIVER NODULE
I: UTERUS, CERVIX, RIGHT TUBE AND OVARY, LEFT TUBE
J: RECTO SIGMOID COLON
K: DONUT RINGS

Gross Description

The specimens are received in 11 formalin-filled containers, each labeled "
." The first container is labeled "omentum, FS1/X" and holds a white
cassette labeled "FS1" that holds a piece of tan-brown soft tissue measuring 0.3
x 2 x 2.2 cm. It also contains a piece of fatty tissue measuring 1.5 x 4 x 8
cm. It has been sectioned previously to show a hard, tan-brown, diffusely
infiltrating tumor measuring 1.3 x 3.9 x 6.8 cm. Labeled A1 - FS1; A2 -
additional sections from the tumor. Jar 1.

[page 3 of 5]
Patient Name:

DOB:

The second container is labeled "pelvic mass" and holds a cystic mass weighing 471 grams and measuring 14.5 x 12 x 12 cm. The surface is irregular and focally covered by necrotic areas. On sectioning, the mass is multicystic, lined by papillary, fungating projections that range in size from 0.2 to 2 cm in diameter. The cysts are filled with serous fluid. There is a solid white homogeneous area within the tumor wall, measuring 3 x 4 cm in diameter. Labeled B1-B8. Jar 3.

The third container is labeled "mesentery" and holds two pieces of tan-brown soft tissue measuring, in aggregate, 1 x 4.5 x 7.8 cm. The mesentery appears to be diffusely involved by a tan-brown tumor that measures 1 x 4 x 5 cm. On sectioning, the tumor is gray-white, homogeneous, with no necrotic areas. Labeled C. Jar 1.

The fourth container is labeled "large bowel lesion" and holds multiple pieces of tan-brown soft tissue measuring, in aggregate, 0.4 x 0.4 x 1.3 cm. Labeled D. Jar 0.

The fifth container is labeled "omentum" and holds a piece of fatty tissue grossly consistent with omentum, measuring 0.9 x 1.5 x 14.5 cm. No tumor is grossly identified. Metallic staples are removed. Labeled E1-E5. Jar 1.

The sixth container is labeled "falciform ligament" and holds two pieces of tan-brown soft tissue measuring 0.9 x 1.5 x 4 cm. There is a gray-white, irregular area suspicious for metastasis, measuring 0.9 x 1.5 x 2.5 cm. Labeled F. Jar 1.

The seventh container is labeled "right hemidiaphragm peritoneum" and holds a piece of tan-brown soft tissue measuring 0.3 x 8 x 9.5 cm. It is diffusely infiltrated by lesions suspicious for metastasis, measuring 1.0 to 0.4 cm in diameter. Labeled G. Jar 1.

The eighth container is labeled "liver nodule" and holds a piece of tan-brown soft tissue measuring 0.3 x 0.5 x 1.5 cm. Labeled H. Jar 0.

The ninth container is labeled "uterus, cervix, left tube and right tube and ovaries." It holds a uterus with cervix and adnexae that weigh 113 grams. The uterus is severely distorted by the presence of surface adhesions and intramyometrial leiomyomata. The uterus measures 4.5 cm in width, 1.7 cm from anterior to posterior, and 8 cm from fundus to lower uterine segment. The cervix measures 0.9 cm in length and 2.5 cm in diameter. The cervix is covered by gray-white, unremarkable mucosa. The anterior and posterior uterine surface has adhesions and areas suspicious for tumor implants. These areas are mainly located at the right anterior uterine surface and fundus. They measure 2 x 1.5 cm in aggregate. The uterus is bivalved to show a distorted endometrial cavity covered by unremarkable endometrium, with an average thickness of 2 mm. No endometrial lesions are grossly identified. Multiple intramyometrial and subserosal leiomyomas are identified, ranging in size from 0.3 to 1.5 x 2.7 x 3 cm. The leiomyomas are gray-white, with a whorled appearance. No areas of necrosis or hemorrhage are identified. The average myometrial thickness is 1.3 cm. The right fallopian tube measures 4.5 cm in length and 1 cm in average diameter. The surface is remarkable for the presence of adhesions. The right ovary is gray-white and measures 0.9 x 2 x 2.5 cm. On sectioning, the stroma is tan-brown and unremarkable. The left fallopian tube is not grossly identified. There is an area, tan-brown, adhered to the uterine fundus, that may represent the left ovary. This area is covered by hemorrhage and measures 1.5 x 2 x 2.5 cm. Labeled I1 - anterior cervix; I2 - posterior cervix; I3 - anterior endometrium; I4 - posterior endometrium; I5, I6 - leiomyomata; I7 - serosa with possible implants; I8 - right fallopian tube; I9 - right ovary; I10 - putative left ovary. Jar 4.

The tenth container is labeled "rectosigmoid colon" and holds a piece of large intestine measuring 15 cm in length and 4.5 cm in average circumference. The

[page 4 of 5]
Patient Name:

DOB:

specimen is unoriented and is closed on one of the ends by a staple line measuring 4.5 cm. Attached to the specimen is pericolic fat that is irregular and appears to be diffusely infiltrated by tumor. The pericolic fat measures 14 cm in length and 3 cm in width. The areas suspicious for involvement by tumor measures ~9 x 5 cm in aggregate. The tumor appears to involve the mesenteric fat only, without involvement of the colonic wall. The colon mucosa is tan-brown, folded, with no mucosal lesions. Labeled J1 - large intestine margins; J2, J3 - tumor; J4 - unremarkable colon. Jar 4. The eleventh container is labeled "donut ring bowel" and holds two unoriented pieces of bowel grossly consistent with donut. The mucosa is tan-brown and unremarkable. No lesions are identified. Labeled K1. Jar 1.

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

HISTOPATHOLOGIC TYPE

The histologic diagnosis is serous adenocarcinoma

TUMOR LOCATION

The location of the primary tumor is the left ovary only

HISTOLOGIC GRADE

The histologic grade is poorly differentiated (G3)

TUMOR INVASION

Tumor is identified on the ovarian surface(s)

Tumor does invade the adjacent fallopian tube/peritubal soft tissue

TUMOR INVOLVEMENT

Tumor involvement of the pelvic peritoneum/soft tissue is present

Metastatic involvement of the extrapelvic peritoneum is present

Metastatic involvement of the omentum is present

TUMOR SIZE

The maximum dimension of tumor implants outside the true pelvis is greater than or equal to 2 cm

PRIMARY TUMOR (T)

Based on the above information, the primary tumor is classified as macroscopic peritoneal metastasis beyond pelvis more than 2 cm in greatest dimension or regional lymph node metastasis (T3c/IIIC)

REGIONAL LYMPH NODES (N)

The regional lymph nodes are classified as regional lymph node metastasis (N1)

The total number of regional lymph nodes examined is 1

The total number of metastatically-involved lymph nodes is 1

Extranodal extension by tumor metastases is absent

DISTANT METASTASIS (M)

The status of distant tumor site cannot be assessed (MX)

STAGE GROUPING

The Final AJCC/UICC/FIGO stage is T3C/N1/M0 (Stage IIIC)

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

[page 5 of 5]
Patient Name:

DOB:

Source: NCI Genomic Data Commons file aa9baa26-8d1d-4cf4-91d8-b63c65e390aa (TCGA-24-0968.887A21BF-12C4-47C7-A48D-A7FAA05C57B2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).